Surgical pathology report (de-identified scan), TCGA case TCGA-P3-A6T2, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site  Fred Hutchinson, specimen TCGA-P3-A6T2-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Carcinoma, squamous cell NOS
8670/3
Site: Buccal mucosa
CD6.D
JW 8/9/13

CASE:

RECEIVED:

CLINICAL DATA:

Lichen planus, left buccal - squamous carcinoma. Today: Left neck dissection, oral lesion excision (buccal), radial forearm free flap.

GROSS DESCRIPTION:

A) Received in formalin designated "..., left level IB" is a 4 x 4 x 2.5 cm yellow lobulated portion of fibrofatty tissue. The specimen is sectioned and there is an eccentric 4 cm in greatest dimension salivary gland identified. It has tan lobulated cut surfaces. No masses or lesions are identified. Surrounding the salivary gland is a scant amount of adipose tissue admixed with three lymph nodes ranging from 0.8 to 1.4 cm in greatest dimension. The lymph nodes are sectioned and have focally white indurated cut surfaces. Representative sections are submitted as follows: A1 - two bisected lymph nodes, one inked blue and one inked orange; A2 - one trisected lymph node; A3-A4 - random salivary gland.

B) Received in formalin designated "..., left level II and III" is a 8 x 3 x 2 cm yellow lobulated portion of fibrofatty tissue. There are two sutures attached to the level II region and three sutures to the level III region. The specimen is sectioned and has yellow lobulated fatty focally fibrous cut surfaces admixed with numerous lymph nodes ranging from 0.1 to 1.5 cm. No masses are identified. The larger lymph nodes are sectioned and have unremarkable cut surfaces. Representative sections are submitted as follows: B1-B3 - candidate level II lymph nodes; B4 - two bisected level II lymph nodes, one inked blue and one inked orange; B5-B6 - candidate level II lymph nodes; B7 - two bisected level II lymph nodes, one inked blue and one inked orange; B8 - candidate level III lymph nodes.

C) Received fresh designated "..., gingival mucosa" are two fragments of tissue measuring 0.2 and 0.3 cm in greatest dimension, which is entirely submitted for frozen section diagnosis, then thawed and submitted in cassette CFS1.

D) Received in formalin designated "..., left buccal mass" is a 4.5 x 3.7 x 2.5 cm portion of tan and brown tissue. The mucosal surface is remarkable for a 3.6 x 2.6 cm exophytic, pale tan lesion with adherent blood on the surface that is raised 1.2 cm above the adjacent mucosa. There is smooth, glistening, gray-brown mucosa around three of the four sides of this lesion; however, the lesion abuts the fourth side and appears transected. The deep surface has fibrofatty tissue with no gross tumor. No orientation is provided to the specimen; however, the side where the lesion abuts the margin is inked black and arbitrarily designated 3 o'clock. The 12 o'clock aspect is inked blue, 9 o'clock orange, and 6 o'clock green. The specimen is serially sectioned from 12-6 o'clock, revealing a 2.6 cm (from 3-9) x 1.6 cm (from superficial to deep) x 4.5 cm 12-6 o'clock lesion that is white on cut surface. This lesion abuts the black ink, appears free of the deep aspect by at least 0.5 cm, and appears to approach the orange ink. The 12 and 6 o'clock most slices are sectioned perpendicularly to these margins, revealing approximately 0.4 cm of normal mucosa between the lesion and the green inked margin, and 0.6 cm of normal mucosa between the lesion and the blue inked margin. Cassettes: D1-D2 - composite of lesion from 9-3 o'clock; D3 - additional representative section in relationship to black ink; D4 -

[page 2 of 3]
additional representative section in relationship to orange ink; D5 - sections in relationship to blue ink; D6 - representative sections in relationship to green ink.

E) Received fresh designated "..., superior buccal margin" are two pieces of tan tissue measuring 0.2 and 0.5 cm in greatest dimension, which are inked black and submitted entirely for frozen section diagnosis, and then thawed and submitted in cassette E/F/GFS1.

F) Received fresh designated "..., inferior buccal margin" is a 0.7 x 0.2 x 0.3 cm portion of tan and red tissue, which is inked blue and submitted entirely for frozen section diagnosis, then thawed and submitted in cassette E/F/GFS1.

G) Received fresh designated "..., tongue margin" is a 0.8 x 0.3 x 0.2 cm portion of tan and red tissue, which is inked orange and submitted entirely for frozen section diagnosis, then thawed and submitted in cassette E/F/GFS1.

H) Received in formalin designated "..., left molar left posterior margin" is a 2 x 0.8 x 0.5 cm premolar. It has a central silver amalgam. There is a scant amount of soft tissue received in the container measuring 0.8 x 0.8 x 0.1 cm in aggregate. The soft tissue minus the tooth is entirely submitted in cassette H1.

INTRAOPERATIVE CONSULTATION:

CFS) Cauterized fibrous tissue, inflammatory cells, and granulation tissue with squamous mucosa; no carcinoma and no definitive high-grade dysplasia

EFS, FFS, GFS) No carcinoma or high-grade dysplasia

FINAL DIAGNOSIS:

D) Mouth, left buccal mass, excision: Invasive, moderately-differentiated, keratinizing squamous cell carcinoma, with the following features:

1. 4.5 cm in greatest dimension.
2. An in-situ component is identified.
3. Carcinoma invades submucosal fat and skeletal muscle.
4. This invasive front infiltrates as angulated cords of malignant cells.
5. Perineural invasion identified.
6. Squamous carcinoma extensively involves arbitrarily designated 3 o'clock margin (see gross description); the remaining margins appear uninvolved by carcinoma.
7. Minor salivary gland with no involvement by carcinoma.
8. Minimum pathologic stage: pT3, N2b, MX.

A, B) Lymph nodes, left levels IB, II, and III, excisions: 2 of 42 lymph nodes positive for metastatic squamous cell carcinoma, including:

1. 2/3 level IB nodes, with the largest focus of carcinoma measuring 1.0 cm in dimension, with no definite extranodal invasion seen.
2. 0/34 level II nodes.
3. 0/5 level III nodes.
4. No extranodal extension identified.
5. Greatest dimension of metastatic carcinoma in lymph node is 0.9 cm.
6. Salivary gland negative for carcinoma.

[page 3 of 3]
C, E, F, G, H) Mouth, gingival mucosa, superior buccal margin, inferior buccal margin, tongue margin, and left molar left posterior margin, respectively, biopsies: No carcinoma identified.

Procedures used to establish the diagnosis:
Routine

Source: NCI Genomic Data Commons file 240fa163-e54b-4f8f-9cf5-afa126e3c2f0 (TCGA-P3-A6T2.7574F56F-614F-4AF4-85D9-63D927595BAF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).